Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6165, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6165-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

SURGICAL PATHOLOGY REPORT

* Addendum *

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with left sigmoid colon cancer.

Specimens Submitted:

- 1: SP: Sigmoid colon; resection
- 2: SP: Additional distal margin
- 3: SP: Proximal margin
- 4: SP: Distal margin

DIAGNOSIS:

- 1. SP: Sigmoid colon; resection:

Tumor Type:

Adenocarcinoma with mucinous features (<50% mucinous component)

Histologic Grade:

Moderately differentiated

Tumor Location:

Sigmoid colon

Tumor Size:

Length is 2.2 cm

Width is 1.5 cm

Maximal thickness is 0.8 cm

Tumor Budding:

Absent

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Not identified

Deepest Tumor Invasion:

Subserosal adipose tissue and/or mesenteric fat

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Suspected

Large Venous Invasion:

Not Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

** Continued on next page **

[page 2 of 4]
Not Identified

Non-Neoplastic Bowel:

Unremarkable

Tattoo pigment is identified consistent with the site of a prior procedure

Lymph Nodes:

Number with metastasis: 0

Total number examined: 20

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N0 (No regional lymph node metastasis)

2. COLON, "ADDITIONAL DISTAL MARGIN"; RESECTION:
-BENIGN SEGMENT OF COLON WITH NO PATHOLOGIC DIAGNOSIS.
3. COLON, "PROXIMAL MARGIN"; RESECTION:
-BENIGN SEGMENT OF COLON WITH NO PATHOLOGIC DIAGNOSIS.
4. COLON, "DISTAL MARGIN"; RESECTION:
-BENIGN SEGMENT OF COLON WITH NO PATHOLOGIC DIAGNOSIS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1.) The specimen is received fresh and is labeled "sigmoid colon, distal end is open". It consists of a sigmoid colon that measures 13.5 cm in length and 7.5 cm in greatest circumference. The serosal surface is tan-red and smooth. The proximal margin is inked black and the distal margin is inked blue. The specimen is opened to reveal a tumor that is located 5.0 cm from the proximal margin and 8.0 cm from the distal margin. The tumor measures 2.2 cm in length and 1.5 cm in width. Serial sectioning reveals tumor invasion to a depth of 0.8 cm, which is 0.5 cm from the closest radial margin. The remaining mucosa shows no gross anomalies. Pericolonic and peri-rectal adipose tissue is thoroughly examined for lymph nodes, and all possible

** Continued on next page **

[page 3 of 4]
nodes are submitted. Representative sections are submitted. TPS is submitted.

Summary of sections:

PM - proximal margin

DM - distal margin

T - tumor

U - uninvolved mucosa

LN - lymph nodes

BLN - bisected lymph node

2.) The specimen is received in formalin, labeled "additional distal margin" and consists of an unoriented portion of colon measuring 1.2 cm in length and 2.0 cm in circumference. The serosa is tan-red and grossly unremarkable. The mucosa is tan-gray and grossly unremarkable. The specimen is entirely submitted.

Summary of sections:

U - undesignated

3.) The specimen is received in formalin, labeled "proximal margin" and consists of a silver metal anastomotic pin measuring 7.5 X 2.8 X 1.5 cm. At the center of the pin, a 3.2 cm plastic piece is noted. A ring of pink tan soft tissue is attached measuring 2.0 x 1.8 x 1.0 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures are noted. The sutures are removed and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

4.) The specimen is received in formalin, labeled "distal margin" and consists of a portion of pink tan soft tissue measuring 2.0 x 1.8 x 1.0 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures are noted. The sutures are removed and the specimen is entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

** Continued on next page **

[page 4 of 4]
Part 1: SP: Sigmoid colon; resection

Block	Sect.	Site	PCs
2		BLN	4
1		DM	1
5		LN	15
1		PM	1
5		T	5
1		U	1

Part 2: SP: Additional distal margin

Block	Sect.	Site	PCs
2		U	2

Part 3: SP: Proximal margin

Block	Sect.	Site	PCs
2		U	2

Part 4: SP: Distal margin

Block	Sect.	Site	PCs
2		U	2

Addendum Diagnosis

1. Colon, sigmoid; resection:

- The focus suspicious for lymphovascular invasion is lost on deeper levels. An immunohistochemical stain for D2-40 does not provide evidence for lymphovascular invasion.

** End of Report **

Source: NCI Genomic Data Commons file d0279267-2534-4cc3-a6e3-a895fe153859 (TCGA-CM-6165.8837AC56-AD16-4BB7-9CEA-DC712E0AE524.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).